Gene-level copy-number profile of tumor specimen HCM-BROD-0014-C71-01A from HCMI case HCM-BROD-0014-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.3 years (24,957 days).
Specimen HCM-BROD-0014-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 957f45ed-9309-466b-8f7e-92601234fde5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0014-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/3476ed23-6b05-4f8c-83da-4dd402744366

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 9,439; copy number 2: 44,005; copy number 3: 5,374; copy number 4: 21; copy number 16: 16; copy number 151: 3; copy number 162: 1; copy number 163: 6; copy number 171: 6; copy number 174: 9.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,508,806, 3 genes: AC119751.3, ANKRD20A17P, AC119751.5.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr9:21,524,307–22,455,740, 20 genes (within-gene range 0–1): SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr22:21,207,973–21,227,637, 1 gene (within-gene range 0–2): GGT2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 41 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,555,001–13,825,079, 6 genes, copy number 171: BRWD1P1, PDPN, RNA5SP41, AL359771.1, AL359771.2, PRDM2.
- chr1:204,377,850–204,685,738, 10 genes, copy number 151–163 (within-gene range 2–163): AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2.
- chr4:53,377,641–54,295,272, 2 genes, copy number 16 (within-gene range 2–16): FIP1L1, AC058822.1.
- chr4:53,899,871–54,376,752, 14 genes, copy number 16: AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1.
- chr11:111,602,449–111,879,425, 9 genes, copy number 174 (within-gene range 2–174): SIK2, AP000925.1, RN7SKP273, PPP2R1B, AP001781.1, ALG9, AP001781.2, ALG9-IT1, GNG5P3.

Autosomal genes at a single copy (total copy number 1): 7,236. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
